Gene-level copy-number profile of tumor specimen TCGA-DR-A0ZL-01A from TCGA case TCGA-DR-A0ZL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 53.1 years (19,384 days).
Specimen TCGA-DR-A0ZL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.a2376928-2447-4b6b-a544-9fc2e23c3d94.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DR-A0ZL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03eb004c-c2e3-482b-835d-4acfe6f3fbd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 13,320; copy number 2: 34,078; copy number 3: 5,420; copy number 4: 6,120; copy number 5: 599; copy number 6: 43; copy number 18: 135; copy number 37: 20; copy number 39: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DR-A0ZL-01A-11D-A10T-01): tumor purity 0.49, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 805 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,902,194–198,222,513, 592 genes, copy number 5 (broad region; genes not listed).
- chr7:41,667,168–43,566,001, 22 genes, copy number 5–37 (within-gene range 1–37): INHBA, INHBA-AS1, GLI3, HMGN2P30, LINC01448, TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1.
- chr7:55,019,017–57,837,046, 143 genes, copy number 18–39 (broad region; genes not listed).
- chr11:101,029,624–103,479,863, 48 genes, copy number 5–6 (within-gene range 1–6): PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1.

Autosomal genes at a single copy (total copy number 1): 13,320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
